Somatic mutation profile of tumor specimen TCGA-EY-A212-01A (aliquot TCGA-EY-A212-01A-11D-A14K-09) from TCGA case TCGA-EY-A212, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 84.0 years (30,680 days).
Specimen TCGA-EY-A212-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4e883ed-64af-4d11-96a6-e25cccb2f375.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A212-10A (Blood Derived Normal), aliquot TCGA-EY-A212-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7825a60-9297-4e74-b5d9-6107b09e530a

The open-access MAF lists 68 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 12, Nonsense Mutation 4, Frame Shift Del 3, Intron 3, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>C p.V173L | Missense Mutation (SNP) | VAF 20/26 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; called by muse, mutect2, varscan2
- ABHD16A | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as rs755613611, COSV65451482; called by muse, mutect2, varscan2
- ACSBG2 | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV53122962; called by muse, mutect2, varscan2
- AGAP1 | c.1785G>C p.E595D (on ENST00000304032 / NM_001037131.3; = p.E542D on NM_014914.5) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.779); catalogued as COSV100364287; called by muse, mutect2
- ALPK2 | c.1524G>T p.M508I | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100864222; called by muse, mutect2
- ANTXR2 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.149); catalogued as COSV55020460; called by muse, mutect2, varscan2
- APOOL | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV64272543; called by muse, mutect2, varscan2
- ATP2C1 | c.139A>T p.N47Y | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV60761401; called by muse, mutect2, varscan2
- CBARP | c.80G>A p.R27H (on ENST00000382477; = p.R33H on NM_152769.3) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs200740347, COSV53071269; called by muse, mutect2, varscan2
- CKM | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV53467800; called by muse, mutect2, varscan2
- CRACD | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV51718686; called by muse, mutect2, varscan2
- DCLRE1C | c.1667A>G p.D556G (on ENST00000378278 / NM_001350965.2; = p.D441G on NM_022487.4) | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); catalogued as COSV57955247; called by muse, mutect2, varscan2
- DNAJA4 | c.859G>A p.V287I (on ENST00000343789; = p.V316I on NM_018602.3) | Missense Mutation (SNP) | VAF 59/80 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV59426936; called by muse, mutect2, varscan2
- EFL1 | c.2606T>C p.I869T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV51609177; called by muse, mutect2
- ERCC2 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs139884931; called by muse, mutect2, varscan2
- ETV7 | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV60318371; called by muse, mutect2, varscan2
- FCER1A | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV63668204; called by muse, mutect2, varscan2
- FGFR4 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52808563; called by muse, mutect2, varscan2
- G6PC2 | c.723G>T p.K241N | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56373316; called by muse, mutect2, varscan2
- GLRA2 | c.578T>G p.F193C | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV54346466; called by muse, mutect2, varscan2
- ITFG1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as rs752772791, COSV57754269; called by muse, mutect2, varscan2
- KCNJ3 | c.924G>C p.M308I | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV54542926; called by muse, varscan2
- LUZP1 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | catalogued as rs748500182, COSV56504486; called by muse, mutect2, varscan2
- MAD1L1 | c.1820A>G p.Q607R | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56245272; called by muse, mutect2, varscan2
- NPHP3 | c.2171+1G>A p.X724_splice | Splice Site (SNP) | VAF 31/75 reads (41%) | catalogued as rs1280230808, COSV58632849; called by muse, mutect2, varscan2
- PAMR1 | c.1312C>T p.R438W (on ENST00000619888 / NM_001001991.3; = p.R455W on NM_015430.4) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763793747, COSV53510809; called by muse, mutect2, varscan2
- PATZ1 | c.1847C>G p.S616C | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.965); catalogued as COSV56745593; called by muse, mutect2, varscan2
- PATZ1 | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53231006; called by muse, mutect2, varscan2
- PDE5A | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV53353573; called by muse, mutect2
- PKN3 | c.2026del p.H676Tfs*10 | Frame Shift Del (DEL) | VAF 30/56 reads (54%) | catalogued as COSV52579256; called by mutect2, varscan2
- PLXNC1 | c.719G>A p.W240* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV51581786; called by muse, mutect2, varscan2
- PRAMEF5 | c.1339C>A p.H447N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100871212; called by muse, mutect2, varscan2
- RANBP1 | c.74C>G p.P25R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV52814786; called by muse, mutect2, varscan2
- RASA2 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV53938325, COSV53945274; called by muse, mutect2
- RPL27A | c.282G>C p.K94N | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV58484855; called by muse, mutect2, varscan2
- RRP1B | c.2078C>A p.T693N | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61480205; called by muse, mutect2, varscan2
- SCN8A | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61991132; called by muse, mutect2, varscan2
- SETD5 | c.3266_3267del p.S1089Cfs*16 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs1064796348; called by pindel, varscan2
- SLC14A1 | c.1056G>T p.M352I | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV58933749; called by muse, mutect2, varscan2
- SV2B | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as rs767247777, COSV57700498; called by muse, mutect2, varscan2
- TBC1D9 | c.279G>C p.W93C | Missense Mutation (SNP) | VAF 56/68 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71308568; called by muse, mutect2, varscan2
- TGS1 | c.2374A>G p.R792G | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52702662; called by muse, mutect2, varscan2
- TMED10 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV100339759; called by muse, mutect2
- TMEM222 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372462929; called by muse, mutect2, varscan2
- TRMT10C | c.238T>A p.S80T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV99998258; called by muse, mutect2
- ULK3 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV51513016; called by muse, mutect2, varscan2
- UNC5D | c.1195G>T p.G399C | Missense Mutation (SNP) | VAF 62/79 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV54827309; called by muse, mutect2, varscan2
- ZFHX3 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99196141; called by muse, mutect2
- ZNF124 | c.1015dup p.T339Nfs*9 (on ENST00000543802 / NM_001297568.1; = p.T277Nfs*9 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 45/117 reads (38%) | catalogued as rs746309323; called by mutect2, varscan2
- ZNF30 | c.44C>A p.T15K | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV57855126; called by muse, mutect2, varscan2
- ARID4B | c.1872_1881del p.I624Mfs*9 | Frame Shift Del (DEL) | VAF 62/248 reads (25%) | called by mutect2, pindel, varscan2
- NCOA5 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 5/113 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2
- ALAS1 | c.933G>A p.S311= | Silent (SNP) | VAF 45/123 reads (37%) | catalogued as rs750408882, COSV59627767, COSV59629368; called by muse, mutect2, varscan2
- BRIX1 | c.981T>A p.V327= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV57762244; called by muse, mutect2, varscan2
- CNTROB | c.873C>A p.A291= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV66609187; called by muse, mutect2, varscan2
- KRAS | c.69A>G p.L23= | Silent (SNP) | VAF 44/79 reads (56%) | catalogued as COSV55974879; called by muse, mutect2, varscan2
- MFSD2A | c.1038C>A p.L346= (on ENST00000372809 / NM_001136493.3; = p.L333= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV65686433; called by muse, mutect2, varscan2
- NOX3 | c.1482C>T p.D494= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs764249682, COSV50161000; called by muse, mutect2, varscan2
- NPHP4 | c.3660G>A p.A1220= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs752239401, COSV65397155; called by muse, mutect2, varscan2
- NRP1 | c.1179A>G p.A393= | Silent (SNP) | VAF 54/106 reads (51%) | catalogued as COSV55175566; called by muse, mutect2, varscan2
- PPP1R3A | c.2052C>T p.D684= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as rs779836256, COSV52891134; called by muse, mutect2, varscan2
- SLC12A5 | c.1284C>A p.G428= (on ENST00000454036 / NM_001134771.2; = p.G405= on NM_020708.5) | Silent (SNP) | VAF 37/52 reads (71%) | catalogued as COSV54800256; called by muse, mutect2, varscan2
- SYCP2L | c.2367G>A p.G789= | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as rs1388110623, COSV51656827; called by muse, mutect2, varscan2
- ZFHX4 | c.336C>T p.N112= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV51489898; called by muse, mutect2, varscan2
- ANKS1B | c.3067-6789C>T | Intron (SNP) | VAF 26/68 reads (38%) | catalogued as COSV59123770; called by muse, mutect2, varscan2
- RORA | c.196+51325G>T | Intron (SNP) | VAF 6/95 reads (6%) | catalogued as COSV99832369; called by muse, mutect2
- TTN | c.10360+4630G>C | Intron (SNP) | VAF 3/43 reads (7%) | catalogued as COSV100601509, COSV100604437, COSV60169997; called by muse, mutect2
